Somatic mutation profile of tumor specimen TCGA-HZ-7920-01A (aliquot TCGA-HZ-7920-01A-11D-2201-08) from TCGA case TCGA-HZ-7920, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 71.6 years (26,167 days).
Specimen TCGA-HZ-7920-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c2d01f5-ab7f-407c-9a46-3b20b40561b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-7920-10B (Blood Derived Normal), aliquot TCGA-HZ-7920-10B-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c4734cf-30b6-426c-b3cc-c504dccd1063

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MRTFA | c.611T>G p.V204G | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV100844081; called by muse, mutect2
